Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI3, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI3-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.0 cm; no angio-invasion ; no invasion in rete testis, tunica albuginea, and epididymis. The cord is not involved, including the resection margin.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
W 3/7/14

Source: NCI Genomic Data Commons file 704e471b-e6e6-47f3-a75b-920557e68040 (TCGA-2G-AAI3-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).